Somatic mutation profile of tumor specimen TARGET-10-PARHBI-09A (aliquot TARGET-10-PARHBI-09A-01D) from TARGET case TARGET-10-PARHBI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.9 years (2,883 days).
Specimen TARGET-10-PARHBI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1041f42d-5523-46dd-936f-a739f624aee8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARHBI-10A (Blood Derived Normal), aliquot TARGET-10-PARHBI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0123f4b-0a6c-4639-8c1c-460cee2fdbcd

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Nonsense Mutation 4, In Frame Ins 1, 5'UTR 1, RNA 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 96/177 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); catalogued as rs483352860; ClinVar: not provided; called by muse, mutect2, varscan2
- ARAP3 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.644); catalogued as rs763210159, COSV53350011; called by muse, mutect2, varscan2
- CDH19 | c.2240A>T p.Y747F | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV50956875; called by muse, varscan2
- CDKL3 | c.1473G>T p.K491N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV99528041; called by muse, mutect2
- CPLANE1 | c.8167C>G p.Q2723E | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as CM1511037, COSV57057285; called by muse, mutect2, varscan2
- DNM2 | c.1595G>T p.S532I (on ENST00000355667 / NM_001005360.3; = p.S528I on NM_004945.3) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as COSV58959890; called by muse, mutect2, varscan2
- FEZ1 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs199780980; called by muse, mutect2, varscan2
- HSBP1 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV71139014; called by muse, mutect2, varscan2
- LRP1B | c.11899G>T p.E3967* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV67205940, COSV67282561; called by muse, mutect2, varscan2
- NOTCH1 | c.4817_4818insACCTCC p.F1606delinsLPP | In Frame Ins (INS) | VAF 50/146 reads (34%) | catalogued as COSV53027782, COSV53042984, COSV53043409, COSV53046232, COSV53074253, COSV53074374, COSV53075070, COSV53075246, COSV53075642, COSV53081693, COSV53092183, COSV53095779, COSV53096923, COSV53096963, COSV53097268, COSV5…; called by mutect2, varscan2
- PHF6 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 97/97 reads (100%) | catalogued as COSV59701107, COSV59701200; called by muse, mutect2, varscan2
- PTPRZ1 | c.5578C>A p.Q1860K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.009); catalogued as COSV66432195; called by muse, mutect2, varscan2
- RASGRP2 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV62449205; called by muse, varscan2
- REV1 | c.1991G>T p.G664V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284310338; called by muse, mutect2, varscan2
- RP1 | c.1242T>G p.D414E | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV55114457; called by muse, mutect2, varscan2
- RPL9 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV54695471, COSV54696781; called by muse, mutect2, varscan2
- TTLL10 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV64962612; called by muse, mutect2, varscan2
- ZNF716 | c.743A>T p.K248I | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV101348640, COSV70780324; called by muse, mutect2, varscan2
- HECTD4 | c.6718G>T p.V2240L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- MCF2 | c.2299G>T p.E767* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | called by muse, varscan2
- SLC51A | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.259); called by muse, mutect2
- SUZ12 | c.1874+1G>T p.X625_splice | Splice Site (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- ZFHX2 | c.5674G>T p.E1892* | Nonsense Mutation (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- AK7 | c.1233G>T p.A411= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs764939853; called by mutect2, varscan2
- EBF2 | c.75G>A p.S25= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV101282243; called by muse, mutect2, varscan2
- GPRASP1 | c.1113C>A p.I371= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- LVRN | c.492G>A p.P164= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1210261776; called by muse, mutect2, varscan2
- MCF2 | c.732G>T p.L244= | Silent (SNP) | VAF 43/43 reads (100%) | catalogued as rs1041714115; called by muse, mutect2, varscan2
- PCDHB16 | c.774C>A p.G258= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- AC243919.1 | n.361G>A | RNA (SNP) | VAF 44/362 reads (12%) | called by muse, varscan2
- FAS | c.-132C>A | 5'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- SEPTIN1 | c.*282C>T | 3'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, varscan2
